Somatic mutation profile of tumor specimen TCGA-SX-A7SQ-01A (aliquot TCGA-SX-A7SQ-01A-12D-A35Z-10) from TCGA case TCGA-SX-A7SQ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 48.4 years (17,696 days).
Specimen TCGA-SX-A7SQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab657f12-2314-4c91-a33d-1331d36e881c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A7SQ-10A (Blood Derived Normal), aliquot TCGA-SX-A7SQ-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a02468a-c694-4a9f-84c7-183bda738b93

The open-access MAF lists 99 somatic variants for this specimen: 65 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 32, Frame Shift Del 6, Nonsense Mutation 2, Frame Shift Ins 2, Splice Region 2, 5'Flank 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3280C>T p.H1094Y | Missense Mutation (SNP) | VAF 61/105 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913244, CM993668, COSV59256829; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV60625095; called by muse, mutect2, varscan2
- ARHGEF7 | c.1157T>G p.M386R (on ENST00000375741 / NM_001113511.2; = p.M208R on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99520874; called by muse, mutect2, varscan2
- CAPN15 | c.3097A>T p.I1033F | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99562131; called by muse, mutect2, varscan2
- CBWD3 | c.308T>A p.L103H | Missense Mutation (SNP) | VAF 131/714 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100793904; called by muse, mutect2, varscan2
- CCSAP | c.662A>C p.K221T | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99497244; called by muse, mutect2, varscan2
- CLASP2 | c.4134G>T p.K1378N (on ENST00000359576; = p.K1377N on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV100222405; called by muse, mutect2, varscan2
- DDX5 | c.1595A>G p.N532S | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.033); catalogued as COSV99857568; called by muse, mutect2, varscan2
- DLG2 | c.455G>C p.R152P | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99712348, COSV99716146, COSV99717873; called by muse, mutect2, varscan2
- DSCAM | c.5704C>A p.P1902T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101258981, COSV68020088; called by muse, mutect2
- ECT2 | c.2508G>C p.K836N (on ENST00000392692 / NM_001349098.2; = p.K805N on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 259/445 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99220851; called by muse, mutect2, varscan2
- EFHC1 | c.1870C>G p.H624D | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100931866; called by muse, mutect2, varscan2
- ENTR1 | c.152T>A p.F51Y | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.146); catalogued as COSV100047991; called by muse, mutect2, varscan2
- EXOC2 | c.2261A>C p.E754A | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100032630; called by muse, mutect2, varscan2
- EZH1 | c.1376T>C p.L459P | Missense Mutation (SNP) | VAF 65/114 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV101331342; called by muse, mutect2, varscan2
- FAM160A2 | c.59C>A p.P20H | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99791674; called by muse, mutect2, varscan2
- FOXK2 | c.572C>G p.A191G | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.694); catalogued as COSV100081769; called by muse, mutect2, varscan2
- FREM2 | c.8534G>T p.R2845L | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV99746623; called by muse, varscan2
- FZD5 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs751492461, COSV99776177; called by muse, mutect2, varscan2
- GLYCTK | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99980598; called by muse, mutect2, varscan2
- GPCPD1 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100980066; called by muse, mutect2, varscan2
- GPX8 | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 86/148 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV99696464; called by muse, mutect2, varscan2
- HAP1 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.659); catalogued as COSV100169376; called by muse, mutect2, varscan2
- ICE1 | c.5357T>C p.L1786S | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.446); catalogued as COSV99663617; called by muse, mutect2, varscan2
- IWS1 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 7/88 reads (8%) | catalogued as COSV99766977; called by muse, mutect2
- MPP2 | c.150G>A p.K50= | Splice Region (SNP) | VAF 35/102 reads (34%) | catalogued as rs929352171, COSV99289856; called by muse, mutect2, varscan2
- MSH2 | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs587782567, COSV99253098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTCL1 | c.4004G>T p.R1335M (on ENST00000306329 / NM_001378206.1; = p.R1016M on NM_015210.4) | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100093291; called by muse, mutect2, varscan2
- MYO18B | c.4434G>A p.K1478= | Splice Region (SNP) | VAF 31/61 reads (51%) | catalogued as rs1321726012, COSV100122491; called by muse, mutect2, varscan2
- NUP93 | c.1053G>T p.W351C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100359878, COSV57433235; called by muse, mutect2, varscan2
- OR2C3 | c.735C>A p.H245Q | Missense Mutation (SNP) | VAF 93/186 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63576012; called by muse, mutect2, varscan2
- PCDHGB2 | c.2396C>A p.P799H | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV99529721; called by muse, mutect2, varscan2
- PGC | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1360043586, COSV100756845; called by muse, mutect2, varscan2
- PMFBP1 | c.1577T>A p.I526N (on ENST00000537465; = p.I521N on NM_031293.3) | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as COSV99400071; called by muse, varscan2
- PROS1 | c.379A>G p.N127D | Missense Mutation (SNP) | VAF 13/340 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.142); catalogued as COSV100820176; called by muse, mutect2
- PRPF38B | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100898174, COSV64224172; called by muse, mutect2, varscan2
- RBM39 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 164/270 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53613891, COSV99488220; called by muse, mutect2, varscan2
- RGS7 | c.811A>G p.R271G | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1442901420, COSV100464283; called by muse, mutect2, varscan2
- RIOX1 | c.1372T>C p.F458L | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV100407895; called by muse, mutect2, varscan2
- RNF213 | c.10888G>A p.G3630S | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV100299602; called by muse, mutect2, varscan2
- RORA | c.887A>G p.Q296R (on ENST00000335670 / NM_134261.3; = p.Q321R on NM_002943.3) | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV99832117; called by muse, mutect2, varscan2
- SCNN1B | c.1266C>A p.D422E | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV56302927; called by muse, mutect2, varscan2
- SCUBE1 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs147314688; called by muse, mutect2, varscan2
- SHISA3 | c.161C>A p.T54N | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV100069769; called by muse, mutect2
- SLMAP | c.1348G>A p.E450K (on ENST00000428312 / NM_001377924.1; = p.E512K on NM_007159.5) | Missense Mutation (SNP) | VAF 76/138 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); catalogued as COSV99907971; called by muse, mutect2, varscan2
- SRRM2 | c.4334C>G p.P1445R | Missense Mutation (SNP) | VAF 82/140 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV100070083; called by muse, mutect2, varscan2
- STAB2 | c.7655G>T p.*2552Lext*19 | Nonstop Mutation (SNP) | VAF 102/167 reads (61%) | catalogued as COSV101185596; called by muse, mutect2, varscan2
- SUFU | c.821C>A p.A274D | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV100882847; called by muse, mutect2, varscan2
- TDRD1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 90/195 reads (46%) | catalogued as COSV99313972; called by muse, mutect2, varscan2
- TECTA | c.148A>G p.K50E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.026); catalogued as COSV99878447; called by muse, mutect2, varscan2
- THBS4 | c.2277T>G p.I759M | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100644181; called by muse, mutect2, varscan2
- THSD7A | c.3990C>G p.D1330E | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101439715; called by muse, mutect2, varscan2
- TINAG | c.1084A>T p.T362S | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.239); catalogued as COSV99448380; called by muse, mutect2, varscan2
- TMEM178A | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99931734; called by muse, mutect2, varscan2
- TSSK1B | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 60/92 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV101180941; called by muse, mutect2, varscan2
- UNKL | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV100061194; called by muse, mutect2, varscan2
- ZIC1 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 85/136 reads (63%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.989); catalogued as COSV99291457; called by muse, mutect2, varscan2
- ABCA5 | c.1707del p.D569Efs*3 | Frame Shift Del (DEL) | VAF 38/79 reads (48%) | called by mutect2, pindel, varscan2
- ATP8A2 | c.3329del p.K1110Sfs*18 | Frame Shift Del (DEL) | VAF 66/243 reads (27%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.3101del p.K1034Rfs*33 | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | called by mutect2, pindel, varscan2
- C19orf44 | c.1099_1105del p.L367Vfs*93 | Frame Shift Del (DEL) | VAF 88/231 reads (38%) | called by mutect2, pindel, varscan2
- EFL1 | c.189del p.E63Dfs*8 | Frame Shift Del (DEL) | VAF 72/198 reads (36%) | called by mutect2, pindel, varscan2
- HIRA | c.2313_2314insAT p.L772Ifs*38 | Frame Shift Ins (INS) | VAF 42/118 reads (36%) | called by mutect2, pindel*, varscan2*
- LRPAP1 | c.667dup p.E223Gfs*27 | Frame Shift Ins (INS) | VAF 25/54 reads (46%) | called by mutect2, pindel, varscan2
- RPN1 | c.357del p.A120Lfs*56 | Frame Shift Del (DEL) | VAF 35/153 reads (23%) | called by mutect2, varscan2
- ABCA2 | c.6261C>T p.T2087= (on ENST00000614293; = p.T2057= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 79/179 reads (44%) | catalogued as COSV99686785; called by muse, mutect2, varscan2
- ANPEP | c.312G>A p.K104= | Silent (SNP) | VAF 44/84 reads (52%) | catalogued as rs776859820, COSV100262564; called by muse, mutect2, varscan2
- ARAP1 | c.796C>T p.L266= (on ENST00000393609 / NM_001040118.2; = p.L21= on NM_015242.4) | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as rs779841363, COSV100501514, COSV61989909; called by muse, mutect2, varscan2
- CAPN15 | c.3096G>A p.V1032= | Silent (SNP) | VAF 50/233 reads (21%) | catalogued as COSV99562130; called by muse, mutect2, varscan2
- CAVIN3 | c.192G>A p.L64= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100392401; called by muse, mutect2, varscan2
- CCDC146 | c.2547C>T p.F849= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs770158077, COSV99592083; called by muse, mutect2, varscan2
- CCNYL1 | c.906A>T p.A302= (on ENST00000295414 / NM_001330218.2; = p.A232= on NM_152523.2) | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV99775681; called by muse, mutect2, varscan2
- CCT6A | c.1260A>G p.E420= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as COSV99303208; called by muse, mutect2, varscan2
- DSP | c.3009C>T p.Y1003= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as COSV101131171; called by muse, mutect2, varscan2
- EPS15L1 | c.573G>A p.V191= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as COSV99932649; called by muse, mutect2, varscan2
- FCRLB | c.540C>A p.P180= | Silent (SNP) | VAF 68/137 reads (50%) | catalogued as COSV100396066; called by muse, mutect2, varscan2
- GRM6 | c.1599C>T p.G533= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs145365816; called by muse, mutect2, varscan2
- KBTBD3 | c.1707G>T p.V569= | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as rs745736380, COSV101595662; called by muse, mutect2, varscan2
- MAN2A2 | c.1473G>A p.G491= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV100847743; called by muse, mutect2, varscan2
- MZT2A | c.126G>A p.E42= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs1370529978, COSV100520793; called by muse, mutect2, varscan2
- NFE2L3 | c.1245A>T p.P415= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV99283458; called by muse, mutect2, varscan2
- PGC | c.183G>C p.V61= | Silent (SNP) | VAF 50/92 reads (54%) | catalogued as COSV100756846; called by muse, mutect2, varscan2
- PMFBP1 | c.1578C>T p.I526= (on ENST00000537465; = p.I521= on NM_031293.3) | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV99400067; called by muse, varscan2
- PRPSAP2 | c.144A>G p.K48= | Silent (SNP) | VAF 43/77 reads (56%) | catalogued as COSV99264313; called by muse, mutect2, varscan2
- SIN3A | c.1386A>G p.T462= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV100845022; called by muse, mutect2, varscan2
- SLC31A1 | c.282G>A p.L94= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV100951909; called by muse, mutect2, varscan2
- SRCIN1 | c.2193G>T p.V731= (on ENST00000621492; = p.V697= on NM_025248.3) | Silent (SNP) | VAF 72/115 reads (63%) | called by muse, mutect2, varscan2
- SYNE4 | c.442C>A p.R148= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV99430805; called by muse, mutect2, varscan2
- TANC2 | c.4317C>T p.V1439= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as rs761772832, COSV101267183; called by muse, mutect2, varscan2
- TGM1 | c.2358G>C p.V786= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99252721; called by muse, mutect2, varscan2
- TMEM51 | c.490C>T p.L164= | Silent (SNP) | VAF 112/268 reads (42%) | catalogued as COSV101051472; called by muse, mutect2, varscan2
- TOMM40L | c.228T>C p.Y76= | Silent (SNP) | VAF 75/152 reads (49%) | catalogued as COSV100915477; called by muse, mutect2, varscan2
- TTC39B | c.327T>C p.D109= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV99894104; called by muse, mutect2, varscan2
- USP42 | c.3801C>T p.V1267= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as rs758935843, COSV100083925; called by muse, mutect2, varscan2
- ZIC1 | c.372G>T p.S124= | Silent (SNP) | VAF 82/134 reads (61%) | catalogued as COSV51553636, COSV99291455; called by muse, mutect2, varscan2
- ZNF14 | c.243A>T p.G81= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as COSV100693960; called by muse, mutect2, varscan2
- ZNF638 | c.5907G>A p.Q1969= | Silent (SNP) | VAF 179/413 reads (43%) | catalogued as COSV100037942; called by muse, mutect2, varscan2
- CLLU1 | chr12:92421041 T>C | 5'Flank (SNP) | VAF 63/100 reads (63%) | catalogued as COSV101029158; called by muse, mutect2, varscan2
- KIR3DX1 | n.997C>T | RNA (SNP) | VAF 30/57 reads (53%) | catalogued as COSV99682892; called by muse, mutect2, varscan2
